Somatic mutation profile of tumor specimen C3N-03420-02 (aliquot CPT0187430006) from CPTAC case C3N-03420, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 66.1 years (24,141 days).
Specimen C3N-03420-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48b98240-96eb-4b3a-8830-6b3d038ecfad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03420-31 (Blood Derived Normal), aliquot CPT0187480002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/799b0a9a-618a-4aa7-b05c-a0ebd7206491

The open-access MAF lists 66 somatic variants for this specimen: 43 protein-altering or splice-affecting, 13 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 13, Intron 6, Nonsense Mutation 5, In Frame Del 3, 3'UTR 2, 5'UTR 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2239_2247del p.L747_E749del | In Frame Del (DEL) | VAF 103/315 reads (33%) | hotspot (GDC flag); catalogued as rs121913436; ClinVar: drug response; called by pindel, varscan2
- AHCYL1 | c.1127A>G p.N376S | Missense Mutation (SNP) | VAF 55/147 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as rs1398269778; called by muse, mutect2, varscan2
- APC | c.2828C>G p.S943* | Nonsense Mutation (SNP) | VAF 15/76 reads (20%) | catalogued as CM021064, CM086470, COSV57334177, COSV57340756, COSV57390748; called by muse, mutect2, varscan2
- ATP6V1H | c.1168C>G p.L390V | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.874); catalogued as rs1157492308; called by muse, mutect2, varscan2
- CSF2RB | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 48/294 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs368852888; called by muse, mutect2, varscan2
- DLG3 | c.357+1G>T p.X119_splice | Splice Site (SNP) | VAF 28/284 reads (10%) | catalogued as CS144343; called by muse, mutect2
- EEF2 | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs1435105012; called by muse, mutect2
- IQCF2 | c.352C>T p.R118* | Nonsense Mutation (SNP) | VAF 114/357 reads (32%) | catalogued as rs562556017, COSV60761700; called by muse, mutect2, varscan2
- OTOA | c.1214C>A p.S405* (on ENST00000286149; = p.S391* on NM_144672.4) | Nonsense Mutation (SNP) | VAF 77/465 reads (17%) | catalogued as COSV53750717, COSV99624132; called by muse, mutect2, varscan2
- PNMA3 | c.60C>A p.C20* | Nonsense Mutation (SNP) | VAF 18/318 reads (6%) | catalogued as rs782639368; called by muse, mutect2
- PYCR3 | c.219C>G p.I73M | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs781243655, COSV55306517; called by muse, mutect2
- RALB | c.67G>A p.G23R | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55603155, COSV55604583; called by muse, mutect2
- SIPA1L3 | c.1387G>A p.A463T | Missense Mutation (SNP) | VAF 36/411 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs776656093; called by muse, mutect2
- SYT12 | c.745G>A p.V249I | Missense Mutation (SNP) | VAF 58/458 reads (13%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as rs199939424; called by muse, mutect2, varscan2
- TANC2 | c.2734G>C p.D912H | Missense Mutation (SNP) | VAF 146/444 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101267311; called by muse, mutect2, varscan2
- TBX3 | c.946C>G p.Q316E (on ENST00000257566 / NM_016569.4; = p.Q296E on NM_005996.4) | Missense Mutation (SNP) | VAF 131/393 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV57469641; called by muse, mutect2, varscan2
- TENM2 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 29/326 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.265); catalogued as rs267600533, COSV72861684; called by muse, mutect2
- TPD52L2 | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 81/253 reads (32%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.67); catalogued as COSV99410835; called by muse, mutect2, varscan2
- ZFHX2 | c.2864C>T p.T955I | Missense Mutation (SNP) | VAF 13/185 reads (7%) | SIFT tolerated (0.13); catalogued as rs924034206; called by muse, mutect2
- ZMYM3 | c.1630C>T p.R544* | Nonsense Mutation (SNP) | VAF 9/93 reads (10%) | catalogued as COSV100077654; called by muse, mutect2
- ATM | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ATP5F1A | c.1451A>T p.Q484L | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DOP1A | c.6905G>T p.C2302F | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FEZF1 | c.1272C>G p.D424E | Missense Mutation (SNP) | VAF 356/691 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GSAP | c.834del p.K279Nfs*3 | Frame Shift Del (DEL) | VAF 24/62 reads (39%) | called by mutect2, pindel, varscan2
- HIVEP1 | c.1375A>G p.T459A | Missense Mutation (SNP) | VAF 62/186 reads (33%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HS6ST3 | c.472G>A p.G158S | Missense Mutation (SNP) | VAF 78/231 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JCAD | c.3811A>G p.M1271V | Missense Mutation (SNP) | VAF 34/370 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); called by muse, mutect2
- KBTBD13 | c.1026_1046del p.G343_H349del | In Frame Del (DEL) | VAF 106/740 reads (14%) | called by mutect2, pindel, varscan2
- MED12 | c.4504_4512del p.L1503_S1505del | In Frame Del (DEL) | VAF 25/90 reads (28%) | called by mutect2, pindel, varscan2
- MUC5B | c.5002A>G p.T1668A | Missense Mutation (SNP) | VAF 11/182 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.103); called by muse, mutect2
- MYLIP | c.968A>T p.Y323F | Missense Mutation (SNP) | VAF 33/526 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2
- NELL1 | c.2041T>A p.F681I | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.543); called by muse, mutect2
- PTPRT | c.2385G>C p.Q795H | Missense Mutation (SNP) | VAF 28/185 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.615); called by muse, varscan2
- RADIL | c.2794G>A p.E932K | Missense Mutation (SNP) | VAF 70/616 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SCN1A | c.4289C>T p.T1430I (on ENST00000303395 / NM_001202435.3; = p.T1419I on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEMA3A | c.394T>A p.C132S | Missense Mutation (SNP) | VAF 18/321 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- SETX | c.7986G>T p.R2662S | Missense Mutation (SNP) | VAF 26/235 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SIGLEC12 | c.1744G>C p.E582Q (on ENST00000291707 / NM_053003.4; = p.E464Q on NM_033329.2) | Missense Mutation (SNP) | VAF 37/290 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- SLC18A1 | c.380A>G p.Q127R | Missense Mutation (SNP) | VAF 27/222 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SMAD2 | c.593A>C p.H198P | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNIK | c.531G>T p.Q177H | Missense Mutation (SNP) | VAF 25/175 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by mutect2, varscan2
- WDR64 | c.2561A>G p.E854G | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ANK1 | c.2070C>T p.H690= | Silent (SNP) | VAF 41/592 reads (7%) | catalogued as rs766385545; called by muse, mutect2
- ASB16 | c.957G>A p.T319= | Silent (SNP) | VAF 58/133 reads (44%) | catalogued as rs760745255; called by muse, mutect2, varscan2
- ATP5F1A | c.76T>C p.L26= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as rs550057616; called by muse, mutect2
- ATXN1 | c.1290C>A p.P430= | Silent (SNP) | VAF 29/514 reads (6%) | called by muse, mutect2
- CLCC1 | c.1506A>T p.T502= (on ENST00000356970 / NM_001377464.1; = p.T452= on NM_015127.5) | Silent (SNP) | VAF 35/227 reads (15%) | called by muse, mutect2, varscan2
- DLGAP4 | c.306C>T p.A102= | Silent (SNP) | VAF 69/375 reads (18%) | called by muse, mutect2, varscan2
- ELAPOR2 | c.603T>C p.Y201= (on ENST00000450689 / NM_001142749.3; = p.Y34= on NM_152748.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 66/157 reads (42%) | catalogued as COSV51889691, COSV99789375; called by muse, mutect2, varscan2
- IFNA10 | c.135A>G p.G45= | Silent (SNP) | VAF 16/302 reads (5%) | called by muse, mutect2
- LRRC4C | c.780G>T p.R260= | Silent (SNP) | VAF 14/170 reads (8%) | called by muse, mutect2
- RBM12B | c.2667T>G p.G889= | Silent (SNP) | VAF 64/374 reads (17%) | called by muse, mutect2, varscan2
- SIGLEC1 | c.729C>A p.I243= | Silent (SNP) | VAF 20/190 reads (11%) | called by muse, mutect2, varscan2
- SMO | c.1944A>C p.P648= | Silent (SNP) | VAF 7/72 reads (10%) | called by mutect2, varscan2
- USP11 | c.1503C>T p.I501= (on ENST00000218348; = p.I458= on NM_001371072.1) | Silent (SNP) | VAF 26/298 reads (9%) | catalogued as rs749581378, COSV99511143; called by muse, mutect2
- CEP164 | c.393+3036A>G | Intron (SNP) | VAF 46/160 reads (29%) | called by muse, mutect2, varscan2
- ERCC6L2 | c.*1531C>G | 3'UTR (SNP) | VAF 40/133 reads (30%) | called by muse, mutect2, varscan2
- FCHO2 | c.*3G>C | 3'UTR (SNP) | VAF 18/140 reads (13%) | called by muse, mutect2, varscan2
- KCNQ2 | c.1247+66C>T | Intron (SNP) | VAF 66/101 reads (65%) | catalogued as rs534116909; called by muse, varscan2
- LTN1 | c.-37G>A | 5'UTR (SNP) | VAF 29/386 reads (8%) | catalogued as rs559678656, COSV100239016; called by muse, mutect2
- MED13L | c.4115-43G>A | Intron (SNP) | VAF 74/203 reads (36%) | called by muse, mutect2, varscan2
- NAE1 | c.218+18C>T | Intron (SNP) | VAF 12/115 reads (10%) | called by muse, mutect2, varscan2
- PTK2 | c.2030+2641C>G | Intron (SNP) | VAF 34/204 reads (17%) | called by muse, varscan2
- TOM1 | c.899+865C>G | Intron (SNP) | VAF 86/222 reads (39%) | called by muse, mutect2, varscan2
- TRMT61A | c.-49C>T | 5'UTR (SNP) | VAF 23/76 reads (30%) | called by muse, mutect2, varscan2
